Gene-level copy-number profile of tumor specimen TCGA-FD-A3NA-01A from TCGA case TCGA-FD-A3NA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-FD-A3NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.93129d0d-3817-4aa2-b886-51726cd264ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3NA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e50fe69-7619-400e-86b5-59ff495d7a33

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 24; copy number 2: 10,170; copy number 3: 25,379; copy number 4: 19,478; copy number 5: 1,330; copy number 6: 2,050; copy number 7: 272; copy number 8: 656; copy number 9: 204; copy number 10: 11; copy number 13: 19; copy number 14: 2; copy number 15: 18; copy number 18: 1; copy number 19: 27; copy number 22: 37; copy number 24: 43; copy number 27: 44; copy number 32: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3NA-01A-11D-A219-01): tumor purity 0.43, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,824,213, 11 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,373 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,118,647–99,632,408, 79 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:64,331,927–68,819,023, 72 genes, copy number 8 (broad region; genes not listed).
- chr8:72,462,311–78,153,913, 81 genes, copy number 9 (broad region; genes not listed).
- chr8:92,460,539–102,810,039, 224 genes, copy number 9–27 (within-gene range 6–27) (broad region; genes not listed).
- chr10:44,712–17,202,054, 296 genes, copy number 7–8 (broad region; genes not listed).
- chr16:7,301,605–12,881,493, 133 genes, copy number 10–32 (broad region; genes not listed).
- chr18:23,004,564–23,672,748, 13 genes, copy number 7–8: RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr18:24,516,699–24,544,154, 1 gene, copy number 7 (within-gene range 3–7): AC007922.3.
- chr18:24,534,551–27,190,698, 38 genes, copy number 7–10 (within-gene range 3–10): LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2.
- chr20:87,250–20,854,642, 394 genes, copy number 8 (broad region; genes not listed).
- chr20:31,303,212–32,101,856, 42 genes, copy number 8 (within-gene range 6–8): DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
